Somatic mutation profile of cancer-model specimen HCM-SANG-0275-C18-85A (3D Organoid; aliquot HCM-SANG-0275-C18-85A-01D-A79M-36), derived from the primary tumor of HCMI case HCM-SANG-0275-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; Tumor grade: G2.
Specimen HCM-SANG-0275-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 97ce83ff-2c3d-4c4f-97a7-2e07fe7f8eb0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-SANG-0275-C18-10B (Blood Derived Normal), aliquot HCM-SANG-0275-C18-10B-01D-A79M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/975dad57-3d19-4e3d-b27a-89ee807e89c0

The open-access MAF lists 153 somatic variants for this specimen: 118 protein-altering or splice-affecting, 31 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 31, Frame Shift Del 8, Nonsense Mutation 5, 3'UTR 3, Frame Shift Ins 2, Splice Site 2, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4127_4128del p.Y1376Cfs*9 | Frame Shift Del (DEL) | VAF 273/375 reads (73%) | catalogued as rs1554085533; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- FBXW7 | c.1745C>T p.S582L (on ENST00000281708 / NM_001349798.2; = p.S502L on NM_018315.5) | Missense Mutation (SNP) | VAF 145/348 reads (42%) | hotspot (GDC flag); SIFT tolerated (0.15); PolyPhen probably damaging (0.991); catalogued as COSV104381731, COSV55890836; called by muse, mutect2, varscan2
- TP53 | c.743G>A p.R248Q | Missense Mutation (SNP) | VAF 361/363 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs11540652, CM920675, COSV52661091, COSV52661580, COSV52675468, COSV52802300; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACR | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 171/420 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs541083098, COSV53360716; called by muse, mutect2, varscan2
- ADCY2 | c.2813T>C p.I938T | Missense Mutation (SNP) | VAF 120/546 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57861105; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3707G>A p.R1236Q | Missense Mutation (SNP) | VAF 332/332 reads (100%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1487215555, COSV51844314; called by muse, mutect2, varscan2
- APBB1 | c.88G>A p.A30T | Missense Mutation (SNP) | VAF 261/724 reads (36%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs374705416; called by muse, mutect2, varscan2
- AQP10 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 631/636 reads (99%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs538916652, COSV100270369; called by muse, mutect2, varscan2
- ARRDC1 | c.703C>T p.R235W | Missense Mutation (SNP) | VAF 76/590 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.873); catalogued as rs371706149; called by muse, mutect2, varscan2
- ASPM | c.4876C>G p.L1626V | Missense Mutation (SNP) | VAF 288/437 reads (66%) | SIFT tolerated (0.66); PolyPhen benign (0.05); catalogued as COSV54127038; called by muse, mutect2, varscan2
- BTD | c.1144A>G p.N382D | Missense Mutation (SNP) | VAF 209/416 reads (50%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.584); catalogued as rs147188293; called by muse, mutect2, varscan2
- CEACAM8 | c.136G>T p.A46S | Missense Mutation (SNP) | VAF 106/233 reads (45%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.941); catalogued as COSV54991336; called by muse, mutect2, varscan2
- CHD4 | c.5306A>C p.K1769T (on ENST00000357008 / NM_001363606.2; = p.K1780T on NM_001273.5) | Missense Mutation (SNP) | VAF 115/244 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV58902474; called by muse, mutect2, varscan2
- CSMD3 | c.8419G>A p.E2807K (on ENST00000297405 / NM_001363185.1; = p.E2638K on NM_052900.3) | Missense Mutation (SNP) | VAF 76/438 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.006); catalogued as rs765143806, COSV52133249; called by muse, varscan2
- CTCFL | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 555/700 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1426082271; called by muse, mutect2, varscan2
- CTU2 | c.736C>T p.R246W | Missense Mutation (SNP) | VAF 148/448 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767710092; called by muse, varscan2
- DAO | c.856C>T p.R286C | Missense Mutation (SNP) | VAF 156/386 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768403852, COSV57321630; called by muse, mutect2, varscan2
- EVA1A | c.202G>T p.G68W | Missense Mutation (SNP) | VAF 270/514 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.419); catalogued as COSV52061909; called by muse, mutect2, varscan2
- FAHD2A | c.421G>A p.V141M | Missense Mutation (SNP) | VAF 152/370 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.223); catalogued as rs763675453, COSV51978804; called by muse, varscan2
- FBXW7 | c.2080G>T p.E694* (on ENST00000281708 / NM_001349798.2; = p.E614* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 138/292 reads (47%) | catalogued as COSV55970391; called by muse, mutect2, varscan2
- FGA | c.2569C>T p.R857C | Missense Mutation (SNP) | VAF 112/262 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as rs754725655, COSV57392507, COSV57394460; called by muse, mutect2, varscan2
- FRZB | c.482T>C p.F161S | Missense Mutation (SNP) | VAF 102/220 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.786); catalogued as rs758347224; called by muse, varscan2
- GPR85 | c.1043G>T p.R348L | Missense Mutation (SNP) | VAF 276/437 reads (63%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV51783074; called by muse, mutect2, varscan2
- GSTA3 | c.151A>T p.M51L | Missense Mutation (SNP) | VAF 126/397 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs1363148059; called by muse, mutect2, varscan2
- HMCN1 | c.794G>A p.G265E | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1174339835, COSV99627966; called by muse, mutect2, varscan2
- HSD17B2 | c.910C>T p.R304W | Missense Mutation (SNP) | VAF 161/490 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as rs776015433, COSV52279046; called by muse, mutect2, varscan2
- KIF5A | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 109/227 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751273893; called by muse, mutect2, varscan2
- KIZ | c.557T>G p.F186C | Missense Mutation (SNP) | VAF 210/1028 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs757134694; called by muse, mutect2, varscan2
- LRFN5 | c.182del p.N61Ifs*14 | Frame Shift Del (DEL) | VAF 115/289 reads (40%) | catalogued as COSV99985692; called by mutect2, pindel, varscan2
- MAGI3 | c.3405T>A p.H1135Q | Missense Mutation (SNP) | VAF 30/372 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.316); catalogued as rs746634291; called by muse, mutect2
- MCHR1 | c.1157C>T p.T386M | Missense Mutation (SNP) | VAF 207/446 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs200156668, COSV50760931; called by muse, mutect2, varscan2
- MEGF8 | c.7157C>T p.A2386V (on ENST00000251268 / NM_001271938.2; = p.A2319V on NM_001410.3) | Missense Mutation (SNP) | VAF 158/327 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs372558876; called by muse, mutect2, varscan2
- MMP26 | c.566A>C p.K189T | Missense Mutation (SNP) | VAF 36/337 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.321); catalogued as COSV100332173, COSV56173848; called by muse, mutect2, varscan2
- MYF5 | c.274G>T p.E92* | Nonsense Mutation (SNP) | VAF 195/385 reads (51%) | catalogued as rs1272930102; called by muse, mutect2, varscan2
- MYL10 | c.424T>C p.F142L | Missense Mutation (SNP) | VAF 155/492 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.248); catalogued as rs764399042; called by muse, mutect2, varscan2
- OLFM1 | c.1441C>T p.R481C (on ENST00000371793 / NM_001282611.2; = p.R463C on NM_014279.5) | Missense Mutation (SNP) | VAF 81/294 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); catalogued as rs1401300491, COSV53277207; called by muse, mutect2, varscan2
- PCNX2 | c.1640A>C p.E547A | Missense Mutation (SNP) | VAF 229/231 reads (99%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.468); catalogued as rs750731277; called by muse, mutect2, varscan2
- PHLDB2 | c.305A>G p.N102S | Missense Mutation (SNP) | VAF 102/198 reads (52%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs947074837; called by muse, mutect2, varscan2
- PLEC | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 117/1821 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs374957051; called by muse, mutect2
- PRDM14 | c.1119del p.L374Wfs*5 | Frame Shift Del (DEL) | VAF 187/1054 reads (18%) | catalogued as COSV52570564; called by mutect2, pindel, varscan2
- PRKCQ | c.1836G>C p.K612N | Missense Mutation (SNP) | VAF 72/316 reads (23%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.917); catalogued as COSV99577416; called by muse, mutect2
- RSPH14 | c.1012C>T p.R338W | Missense Mutation (SNP) | VAF 189/354 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.424); catalogued as rs767247482; called by muse, mutect2, varscan2
- RYR3 | c.7849G>A p.V2617I (on ENST00000389232; = p.V2618I on NM_001036.6) | Missense Mutation (SNP) | VAF 89/243 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.057); catalogued as rs369629619; ClinVar: likely benign; called by muse, mutect2, varscan2
- SMAD4 | c.229A>C p.T77P | Missense Mutation (SNP) | VAF 161/164 reads (98%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); catalogued as COSV61693559; called by muse, mutect2, varscan2
- STEAP3 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 262/502 reads (52%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.996); catalogued as rs376692800; called by muse, mutect2, varscan2
- TNRC6B | c.1771C>T p.R591W | Missense Mutation (SNP) | VAF 128/294 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs775647766, COSV57299596; called by muse, mutect2, varscan2
- TRPC4 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 139/265 reads (52%) | SIFT tolerated (0.59); PolyPhen benign (0.085); catalogued as rs1296547693; called by muse, mutect2, varscan2
- TTC30A | c.235G>C p.E79Q | Missense Mutation (SNP) | VAF 280/601 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1362114123; called by muse, mutect2, varscan2
- WDR75 | c.2455T>A p.F819I | Missense Mutation (SNP) | VAF 90/185 reads (49%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1423691515; called by muse, mutect2, varscan2
- ZNF841 | c.1513G>A p.G505R (on ENST00000426391 / NM_001369830.1; = p.G621R on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 154/317 reads (49%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.587); catalogued as rs373036711; called by muse, mutect2, varscan2
- A2ML1 | c.2062del p.I688Sfs*5 | Frame Shift Del (DEL) | VAF 132/324 reads (41%) | called by mutect2, pindel, varscan2
- ABCB4 | c.2685dup p.A896Cfs*9 | Frame Shift Ins (INS) | VAF 85/292 reads (29%) | called by mutect2, pindel, varscan2
- ABCC9 | c.389T>C p.F130S | Missense Mutation (SNP) | VAF 68/150 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- ADNP | c.270A>C p.K90N | Missense Mutation (SNP) | VAF 321/867 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- AGPAT3 | c.130C>T p.Q44* | Nonsense Mutation (SNP) | VAF 266/513 reads (52%) | called by muse, mutect2, varscan2
- AOAH | c.740A>G p.K247R | Missense Mutation (SNP) | VAF 113/388 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- AQR | c.1292A>C p.K431T | Missense Mutation (SNP) | VAF 100/203 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- BAIAP2L2 | c.1246G>C p.E416Q | Missense Mutation (SNP) | VAF 139/304 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- C16orf96 | c.627T>G p.F209L | Missense Mutation (SNP) | VAF 179/542 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2, varscan2
- C1QTNF7 | c.745A>G p.I249V | Missense Mutation (SNP) | VAF 137/260 reads (53%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CAPZA1 | c.689A>G p.K230R | Missense Mutation (SNP) | VAF 101/194 reads (52%) | SIFT tolerated (0.24); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CCDC110 | c.1353A>C p.E451D | Missense Mutation (SNP) | VAF 128/255 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.637); called by muse, mutect2, varscan2
- CCDC177 | c.2065C>T p.R689* | Nonsense Mutation (SNP) | VAF 315/657 reads (48%) | called by muse, mutect2, varscan2
- CDK2 | c.219A>C p.E73D | Missense Mutation (SNP) | VAF 110/272 reads (40%) | SIFT tolerated (0.71); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDYL | c.1220A>G p.Y407C (on ENST00000328908 / NM_001368125.1; = p.Y353C on NM_004824.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 329/476 reads (69%) | SIFT deleterious (0.02); PolyPhen benign (0.387); called by muse, mutect2, varscan2
- CLIC6 | c.694G>A p.A232T | Missense Mutation (SNP) | VAF 224/489 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- COL6A5 | c.7779A>C p.E2593D (on ENST00000312481; = p.E2589D on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 89/289 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.659); called by muse, mutect2, varscan2
- CPXCR1 | c.145A>G p.I49V | Missense Mutation (SNP) | VAF 225/442 reads (51%) | SIFT tolerated (0.98); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CRISPLD2 | c.526G>T p.A176S | Missense Mutation (SNP) | VAF 150/492 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- CSMD3 | c.7478del p.G2493Vfs*8 (on ENST00000297405 / NM_001363185.1; = p.G2389Vfs*8 on NM_052900.3) | Frame Shift Del (DEL) | VAF 102/574 reads (18%) | called by mutect2, pindel, varscan2
- CST9L | c.299A>T p.K100I | Missense Mutation (SNP) | VAF 142/701 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DCK | c.239A>G p.N80S | Missense Mutation (SNP) | VAF 128/251 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.465); called by muse, mutect2, varscan2
- DDX11 | c.1349A>G p.K450R | Missense Mutation (SNP) | VAF 118/275 reads (43%) | SIFT tolerated (0.25); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DIAPH1 | c.765G>C p.M255I | Missense Mutation (SNP) | VAF 169/363 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- DLG5 | c.5128G>C p.D1710H | Missense Mutation (SNP) | VAF 244/516 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- EFCAB6 | c.2564del p.N855Ifs*3 | Frame Shift Del (DEL) | VAF 126/295 reads (43%) | called by mutect2, pindel, varscan2
- ELP1 | c.1946A>C p.E649A | Missense Mutation (SNP) | VAF 164/363 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); called by muse, mutect2, varscan2
- FAM118B | c.822T>A p.H274Q | Missense Mutation (SNP) | VAF 178/562 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- HBP1 | c.789G>C p.K263N | Missense Mutation (SNP) | VAF 184/299 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- IFIT3 | c.34del p.I12Sfs*5 | Frame Shift Del (DEL) | VAF 112/279 reads (40%) | called by mutect2, pindel, varscan2
- IGKC | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 214/406 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- KIF14 | c.2318T>G p.F773C | Missense Mutation (SNP) | VAF 275/278 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.571); called by muse, mutect2, varscan2
- KLHL10 | c.1763T>G p.F588C | Missense Mutation (SNP) | VAF 198/394 reads (50%) | SIFT tolerated (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- KLHL7 | c.1497A>T p.E499D (on ENST00000339077 / NM_001031710.3; = p.E451D on NM_018846.5) | Missense Mutation (SNP) | VAF 122/352 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.368); called by muse, mutect2, varscan2
- KMT2C | c.5147T>G p.M1716R | Missense Mutation (SNP) | VAF 202/547 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- LILRA5 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 204/397 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MMRN2 | c.1156A>G p.T386A | Missense Mutation (SNP) | VAF 262/577 reads (45%) | SIFT tolerated (0.87); PolyPhen benign (0); called by muse, mutect2, varscan2
- MPDZ | c.4475dup p.L1493Ffs*42 | Frame Shift Ins (INS) | VAF 152/543 reads (28%) | called by mutect2, pindel, varscan2
- MYF5 | c.275A>T p.E92V | Missense Mutation (SNP) | VAF 188/379 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NAPB | c.691A>T p.M231L | Missense Mutation (SNP) | VAF 85/510 reads (17%) | SIFT tolerated (0.63); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NR1D2 | c.284A>C p.K95T | Missense Mutation (SNP) | VAF 69/177 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- OFD1 | c.590A>T p.E197V | Missense Mutation (SNP) | VAF 155/287 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- OR5D16 | c.978T>G p.I326M | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- OSMR | c.1408G>T p.V470L | Missense Mutation (SNP) | VAF 116/509 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- PCDHGA8 | c.1606G>A p.D536N | Missense Mutation (SNP) | VAF 494/496 reads (100%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PDE6G | c.146+1G>T p.X49_splice | Splice Site (SNP) | VAF 124/249 reads (50%) | called by muse, mutect2, varscan2
- PLPPR3 | c.2049G>T p.E683D (on ENST00000520876 / NM_001270366.2; = p.E711D on NM_024888.2) | Missense Mutation (SNP) | VAF 225/463 reads (49%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRKCD | c.1355T>C p.F452S | Missense Mutation (SNP) | VAF 187/371 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRMT3 | c.1354G>T p.A452S | Missense Mutation (SNP) | VAF 67/234 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.412); called by muse, mutect2, varscan2
- PROS1 | c.523del p.C175Vfs*33 | Frame Shift Del (DEL) | VAF 131/290 reads (45%) | called by mutect2, pindel, varscan2
- PTPRB | c.4694A>G p.K1565R | Missense Mutation (SNP) | VAF 140/269 reads (52%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PTPRQ | c.1847T>A p.I616N (on ENST00000616559; = p.I574N on NM_001145026.2) | Missense Mutation (SNP) | VAF 64/124 reads (52%) | SIFT tolerated (0.91); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- QSER1 | c.1985A>G p.N662S (on ENST00000399302; = p.N791S on NM_001076786.3) | Missense Mutation (SNP) | VAF 110/336 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2
- RIMS2 | c.3728C>T p.S1243F | Missense Mutation (SNP) | VAF 186/790 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RNF111 | c.1501C>T p.H501Y | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ROCK2 | c.914A>T p.K305I | Missense Mutation (SNP) | VAF 96/194 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RYR2 | c.14302G>T p.V4768L | Missense Mutation (SNP) | VAF 63/181 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- SLC2A14 | c.1534C>G p.P512A | Missense Mutation (SNP) | VAF 42/80 reads (53%) | SIFT tolerated (0.05); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLC2A3 | c.1462C>G p.P488A | Missense Mutation (SNP) | VAF 105/629 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.007); called by muse, mutect2
- SOHLH2 | c.319T>C p.F107L | Missense Mutation (SNP) | VAF 78/148 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SYNE2 | c.10299A>T p.E3433D | Missense Mutation (SNP) | VAF 184/356 reads (52%) | SIFT tolerated (0.68); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TEX51 | c.422G>T p.C141F (on ENST00000643416; = p.C117F on NM_001322244.2) | Missense Mutation (SNP) | VAF 204/407 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- TTN | c.21319C>T p.Q7107* (on ENST00000591111; = p.Q6180* on NM_133378.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 85/177 reads (48%) | called by muse, mutect2, varscan2
- WASHC3 | c.563G>C p.S188T | Missense Mutation (SNP) | VAF 103/220 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.267); called by muse, mutect2, varscan2
- WBP4 | c.263-17_275del p.X88_splice | Splice Site (DEL) | VAF 56/149 reads (38%) | called by mutect2, pindel, varscan2
- ZNF600 | c.2021C>A p.T674N | Missense Mutation (SNP) | VAF 152/302 reads (50%) | SIFT deleterious (0.03); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- ZNF85 | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 115/224 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ZNF90 | c.245C>G p.A82G | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.137); called by muse, mutect2
- BCO1 | c.24T>C p.N8= | Silent (SNP) | VAF 137/469 reads (29%) | catalogued as rs746577332; called by muse, mutect2, varscan2
- CAPS2 | c.1014T>C p.N338= | Silent (SNP) | VAF 95/205 reads (46%) | catalogued as COSV60825353; called by muse, mutect2, varscan2
- CD2AP | c.816A>G p.E272= | Silent (SNP) | VAF 122/188 reads (65%) | called by muse, mutect2, varscan2
- DDX42 | c.2577C>T p.H859= | Silent (SNP) | VAF 174/360 reads (48%) | catalogued as rs374435300; called by muse, mutect2, varscan2
- DOT1L | c.1584G>A p.A528= | Silent (SNP) | VAF 120/267 reads (45%) | catalogued as rs376482252, COSV67114210; called by muse, mutect2, varscan2
- DRG2 | c.411G>A p.A137= | Silent (SNP) | VAF 214/482 reads (44%) | catalogued as rs766572713, COSV56727684; called by muse, mutect2, varscan2
- FNDC3A | c.1248A>G p.E416= (on ENST00000492622 / NM_001079673.2; = p.E360= on NM_014923.5) | Silent (SNP) | VAF 100/208 reads (48%) | called by muse, mutect2, varscan2
- GMIP | c.1902G>A p.V634= | Silent (SNP) | VAF 170/373 reads (46%) | called by muse, mutect2, varscan2
- IRAK2 | c.621C>T p.T207= | Silent (SNP) | VAF 184/386 reads (48%) | catalogued as rs771431923, COSV99844265; called by muse, mutect2, varscan2
- KIAA0408 | c.1491C>T p.T497= | Silent (SNP) | VAF 133/538 reads (25%) | catalogued as rs751803238; called by muse, mutect2, varscan2
- KLLN | c.216A>G p.E72= | Silent (SNP) | VAF 185/377 reads (49%) | called by muse, mutect2, varscan2
- LUC7L3 | c.840A>G p.E280= | Silent (SNP) | VAF 195/392 reads (50%) | catalogued as rs774762325; called by muse, mutect2, varscan2
- MC3R | c.198C>T p.N66= | Silent (SNP) | VAF 362/892 reads (41%) | catalogued as rs961326205, COSV54763540; called by muse, mutect2, varscan2
- MEPCE | c.693C>T p.I231= | Silent (SNP) | VAF 181/573 reads (32%) | catalogued as rs780159536; called by muse, mutect2, varscan2
- NBN | c.1335G>A p.R445= | Silent (SNP) | VAF 62/750 reads (8%) | catalogued as rs1554559085; ClinVar: likely benign; called by muse, mutect2
- NOS3 | c.810C>T p.I270= | Silent (SNP) | VAF 99/501 reads (20%) | catalogued as rs746886189; called by muse, mutect2, varscan2
- PCDHGB2 | c.1605C>T p.R535= | Silent (SNP) | VAF 303/612 reads (50%) | catalogued as COSV53902725, COSV53962165; called by muse, varscan2
- PCYOX1 | c.1353T>C p.H451= | Silent (SNP) | VAF 190/428 reads (44%) | catalogued as rs1266591370; called by muse, mutect2, varscan2
- POMT1 | c.9A>T p.G3= | Silent (SNP) | VAF 159/307 reads (52%) | catalogued as COSV57644718; called by muse, mutect2, varscan2
- POU4F2 | c.33G>A p.A11= | Silent (SNP) | VAF 198/384 reads (52%) | called by muse, mutect2, varscan2
- QSER1 | c.1983T>C p.T661= (on ENST00000399302; = p.T790= on NM_001076786.3) | Silent (SNP) | VAF 114/340 reads (34%) | catalogued as rs1036191131; called by muse, mutect2
- RFC1 | c.1212A>G p.E404= | Silent (SNP) | VAF 121/249 reads (49%) | catalogued as rs867380312; called by muse, mutect2, varscan2
- TBCE | c.387A>G p.K129= (on ENST00000366601; = p.K192= on NM_003193.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 139/139 reads (100%) | called by muse, mutect2, varscan2
- TCHHL1 | c.1506A>G p.L502= | Silent (SNP) | VAF 212/655 reads (32%) | called by muse, mutect2, varscan2
- TCTA | c.240G>A p.T80= | Silent (SNP) | VAF 205/389 reads (53%) | catalogued as rs542556038; called by muse, mutect2, varscan2
- TMEM151A | c.846C>T p.Y282= | Silent (SNP) | VAF 200/943 reads (21%) | catalogued as rs757069909, COSV59174823; called by muse, mutect2, varscan2
- TMEM169 | c.429G>A p.T143= | Silent (SNP) | VAF 129/318 reads (41%) | catalogued as rs148862207; called by muse, mutect2, varscan2
- TNRC6B | c.4299G>A p.P1433= (on ENST00000454349 / NM_001162501.2; = p.P1323= on NM_015088.3) | Silent (SNP) | VAF 128/315 reads (41%) | catalogued as rs750851269; called by muse, mutect2, varscan2
- TTN | c.73428A>G p.G24476= (on ENST00000591111; = p.G17052= on NM_003319.4) | Silent (SNP) | VAF 151/340 reads (44%) | called by muse, mutect2, varscan2
- UTRN | c.135T>C p.F45= | Silent (SNP) | VAF 209/342 reads (61%) | called by muse, mutect2, varscan2
- ZNF418 | c.1104A>G p.R368= | Silent (SNP) | VAF 155/346 reads (45%) | called by muse, mutect2, varscan2
- COPS9 | chr2:240129989 C>G | 3'Flank (SNP) | VAF 239/493 reads (48%) | called by muse, mutect2, varscan2
- EFEMP2 | c.*268_*269del | 3'UTR (DEL) | VAF 62/659 reads (9%) | called by pindel, varscan2
- SEPTIN11 | c.*2275C>T | 3'UTR (SNP) | VAF 131/244 reads (54%) | catalogued as rs762546575; called by muse, mutect2, varscan2
- ZDHHC8 | c.*1694del | 3'UTR (DEL) | VAF 306/762 reads (40%) | called by mutect2, pindel, varscan2
